MMRF case MMRF_1810 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/e4e7cbc4-5d41-4d20-8fdf-0328295662ab

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 61 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 61.5 years (22,473 days); ISS stage: I; Days to last known disease status: 1,084 days (3.0 years); Days to last follow up: 1,084 days (3.0 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 994 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 23 days; Days to treatment end: 999 days (2.7 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 159 days; Days to treatment end: 160 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 162 days; Days to treatment end: 162 days.
   Treatment given: Therapeutic agents: Dexamethasone + Elotuzumab + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,090 days (3.0 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,084.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 4.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 411 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Beta 2 Microglobulin 3.2 µg/mL; Lactate Dehydrogenase 3.77 µkat/L; Hemoglobin 5.27 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 2.84 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 19.6 mmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 10.6 g/dL; Glucose 5.67 mmol/L.
- Day 85 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 81.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 9.42 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.87 g/L; Lactate Dehydrogenase 5.08 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 4.61 ×10⁹/L; Absolute Neutrophil 2.88 ×10⁹/L; Platelets 258 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.2 mmol/L; Albumin 33 g/L; Total Protein 6.9 g/dL; Glucose 5.23 mmol/L.
- Day 196 (ECOG 0): M Protein 0.5 g/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 0.49 g/L; Immunoglobulin M 1.24 g/L; Lactate Dehydrogenase 4.43 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 8.5 ×10⁹/L; Absolute Neutrophil 6.8 ×10⁹/L; Platelets 265 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.5 mmol/L; Albumin 42 g/L; Total Protein 7.3 g/dL; Glucose 5.61 mmol/L.
- Day 261 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.233 mg/dL; Immunoglobulin G 7.52 g/L; Immunoglobulin A 0.39 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 3.55 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 281 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 7.2 g/dL; Glucose 5.23 mmol/L.
- Day 359 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 3.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.585 mg/dL; Immunoglobulin G 5.48 g/L; Immunoglobulin A 0.77 g/L; Immunoglobulin M 0.65 g/L; Lactate Dehydrogenase 3.72 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 227 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.32 mmol/L; Albumin 44 g/L; Total Protein 7 g/dL; Glucose 5.61 mmol/L.
- Day 462 (ECOG 0): M Protein 0.1 g/dL; Hemoglobin 8.25 mmol/L; Leukocytes 8.4 ×10⁹/L; Absolute Neutrophil 6.3 ×10⁹/L; Platelets 259 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.39 mmol/L; Glucose 5.28 mmol/L.
- Day 552 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.651 mg/dL; Immunoglobulin G 5.85 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.55 g/L; Lactate Dehydrogenase 4.25 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 230 ×10⁹/L; Creatinine 53.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.1 mmol/L; Albumin 37 g/L; Total Protein 6.7 g/dL; Glucose 5.45 mmol/L.
- Day 642 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.36 mg/dL; Immunoglobulin G 9.49 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 0.72 g/L; Lactate Dehydrogenase 3.92 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.35 mmol/L; Albumin 36 g/L; Total Protein 7.3 g/dL; Glucose 3.91 mmol/L.
- Day 722 (ECOG 0): Lactate Dehydrogenase 3.87 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 50.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.18 mmol/L; Albumin 32 g/L; Total Protein 7.2 g/dL; Glucose 5.12 mmol/L.
- Day 824 (ECOG 0): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.576 mg/dL; Hemoglobin 7.69 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.2 mmol/L; Glucose 10.2 mmol/L.
- Day 908 (ECOG 0): M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 35.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.564 mg/dL; Immunoglobulin G 16.8 g/L; Immunoglobulin A 1.1 g/L; Immunoglobulin M 0.45 g/L; Lactate Dehydrogenase 5.05 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.18 mmol/L; Albumin 31 g/L; Total Protein 7.4 g/dL; Glucose 7.15 mmol/L.
- Day 992 (ECOG 0): M Protein 1.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 156 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.224 mg/dL; Immunoglobulin G 29.8 g/L; Immunoglobulin A 0.88 g/L; Immunoglobulin M 0.33 g/L; Lactate Dehydrogenase 3.23 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.38 mmol/L; Albumin 33 g/L; Total Protein 8.8 g/dL; Glucose 6.77 mmol/L.
- Day 1,069 (ECOG 0): M Protein 2.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 218 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Hemoglobin 5.27 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 111 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.1 mmol/L; Glucose 6.88 mmol/L.

Other clinical attributes
- Day 1: Weight: 88 kg; Height: 177 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1810_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1810_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
